Gene-level copy-number profile of tumor specimen TCGA-VS-A8Q8-01A from TCGA case TCGA-VS-A8Q8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 26.2 years (9,571 days).
Specimen TCGA-VS-A8Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.31d054fb-991f-40f3-80e6-4b464a97be9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8Q8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b2ac8d8-b029-4f63-bb04-5b9d5d2649a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,838; copy number 2: 39,817; copy number 3: 12,105; copy number 5: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8Q8-01A-11D-A37M-01): tumor purity 0.7, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:7,476,875–8,343,262, 58 genes, copy number 5 (within-gene range 3–5): PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L, PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44, AC010336.7, ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3, AC022146.1, CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3.

Autosomal genes at a single copy (total copy number 1): 7,838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
